CCDI case PBBVHF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8aa92b66-396b-4d37-a806-b8799e872632

Demographics
Sex at birth: female; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 13.9 years (5,074 days).

Biospecimens (3 samples)
- Sample 0DI5EH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI5EX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI5FN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
